Surgical pathology report (de-identified scan), TCGA case TCGA-24-1474, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1474-01A (Primary Tumor).

[page 1 of 2]
24-1474

SURGICAL PATHOLOGY REPORT

Other Related Clinical Data:

DIAGNOSIS: OVARY, LEFT, EXCISION

- POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA (FIGO GRADE III/III) (SEE SYNOPTIC)
- NO RESIDUAL OVARY IDENTIFIED

"FALLOPIAN TUBE," LEFT, EXCISION

- NO FALLOPIAN TUBE IDENTIFIED

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- METASTATIC SEROUS ADENOCARCINOMA ON OVARIAN SURFACE
- DETACHED FRAGMENT OF METASTATIC SEROUS ADENOCARCINOMA

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- PORTION OF FALLOPIAN TUBE (FIMBRIA) IDENTIFIED
- NO EVIDENCE OF MALIGNANCY

PERITONEUM, RIGHT UPPER QUADRANT NODULE (INCLUDING FS1), BIOPSY

- METASTATIC SEROUS ADENOCARCINOMA

MESENTERY, SMALL INTESTINE, BIOPSY

- METASTATIC SEROUS ADENOCARCINOMA

OMENTUM, EXCISION

- SINGLE MICROSCOPIC FOCUS OF METASTATIC SEROUS ADENOCARCINOMA WITHIN INFLAMMATORY AND HEMORRHAGIC EXUDATE ON SURFACE OF OMENTUM
- MATURE ADIPOSE TISSUE WITH MESOTHELIAL HYPERPLASIA AND CHRONIC INFLAMMATION

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[page 2 of 2]
Synopsis SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS 1. A neoplasm is PRESENT

2. The HISTOLOGIC DIAGNOSIS is: Serous adenocarcinoma
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are: Left ovary only
4. The FIGO GRADE of the tumor is: III (Tumor composed of >50% solid cellular nests)
5. The NUCLEAR (BRODERS') GRADE of the tumor is: GRADE 2
6. Tumor IS identified on both ovarian surfaces.
7. The presence of tumor invasion of the mesovarium CANNOT BE EVALUATED.
8. Invasion of adjacent fallopian tube CANNOT BE EVALUATED (Fallopian tube is not identified).
9. Tumor invasion of pelvic soft tissue CANNOT BE EVALUATED.
10. Tumor involvement of the pelvic peritoneum CANNOT BE EVALUATED.
11. Metastatic involvement of the EXTRAPELVIC PERITONEUM is PRESENT.
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true pelvis is 5 cm.
14. Metastatic involvement of the uterine serosa CANNOT BE EVALUATED.
15. Metastatic involvement of the endometrium CANNOT BE EVALUATED.
16. Regional lymph node metastases CANNOT BE EVALUATED.
17. The total number of regional lymph nodes examined is 0.
18. The total number of metastatically-involved regional lymph nodes is not applicable.
19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition
T3c	IIIC	Macroscopic
peritoneal metastasis beyond true pelvis measuring > 2 cm in maximum dimension		

THE REGIONAL LYMPH NODES are classified as: NX (Nodal status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as: MX (Status cannot be assessed)

20. The FINAL AJCC/UICC/FIGO STAGE IS: AJCC/UICC/FIGO
at least IIIC

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 93e2dc73-3431-4729-9dcb-1ac73e3b6c5e (TCGA-24-1474.C4D49A95-0478-4399-A5EB-224CA6D16CD7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).